Gene-level copy-number profile of tumor specimen ALCH-AEKY-TTP1-A from ALCHEMIST case ALCH-AEKY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.7 years (22,173 days).
Specimen ALCH-AEKY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bb07f386-2455-48a4-965b-4101feda2d62.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEKY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/1ac099a4-ad0b-4e3c-99c1-d773ca0e5321

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 21,408; copy number 2: 30,921; copy number 3: 4,069; copy number 4: 1,828; copy number 5: 127; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,945,502–88,049,823, 3 genes (within-gene range 0–1): RPL11P3, AC063965.1, MED6P1.
- chr13:19,422,877–20,232,365, 24 genes: TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2, ZMYM2, KRR1P1, AL138688.2, LINC01072, GJA3, PPIAP28, LINC00556, GJB2, AL138688.1, GJB6.
- chr13:65,787,932–65,788,764, 1 gene: HNRNPA3P5.
- chr13:77,779,723–78,659,155, 15 genes: EDNRB-AS1, EDNRB, OBI1-AS1, AL139002.1, RN7SL810P, LINC01069, LINC00446, AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1.
- chr13:107,163,510–107,933,503, 7 genes: FAM155A, SNORD31B, AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 130 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–94,131,832, 10 genes, copy number 5: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2.
- chr3:151,733,916–156,674,446, 76 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:11,956,207–12,359,144, 8 genes, copy number 5 (within-gene range 2–5): DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1.
- chr11:13,152,200–13,496,181, 7 genes, copy number 5: AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.1, AC021269.2, PTH.
- chr11:14,262,846–15,082,342, 14 genes, copy number 5–8 (within-gene range 4–8): SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P.
- chr11:20,131,730–20,575,042, 5 genes, copy number 5: AC068860.1, DBX1, HTATIP2, PRMT3, HMGB1P40.
- chr11:23,370,116–23,893,557, 10 genes, copy number 5: AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1.

Autosomal genes at a single copy (total copy number 1): 21,408. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
